Somatic mutation profile of tumor specimen 0DLV36 from CCDI case PBBZGY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,479 days).
Specimen 0DLV36: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 369c4b12-50be-4b6a-b979-6be1a71e8aa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLV2W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a2119f2-d2b7-432e-ba8f-537e25a3b732

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1915_1917dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 217/923 reads (24%) | catalogued as COSV99072650; called by mutect2, varscan2
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 31/788 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 46/986 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FZD3 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 28/614 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); called by muse, mutect2
- LANCL3 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 187/701 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZC3H11B | c.2162A>G p.E721G | Missense Mutation (SNP) | VAF 164/1207 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DKC1 | c.1173G>T p.L391= | Silent (SNP) | VAF 305/1139 reads (27%) | called by muse, mutect2, varscan2
- EYS | c.1767-8564T>C | Intron (SNP) | VAF 6/35 reads (17%) | called by mutect2, varscan2
